Somatic mutation profile of tumor specimen TCGA-A4-7732-01A (aliquot TCGA-A4-7732-01A-11D-2136-08) from TCGA case TCGA-A4-7732, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 55.4 years (20,226 days).
Specimen TCGA-A4-7732-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de7dedf6-ca59-4e85-956c-4b81e26bccf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7732-10A (Blood Derived Normal), aliquot TCGA-A4-7732-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f29e819-de2f-4a6b-801a-83c43494e0c9

The open-access MAF lists 48 somatic variants for this specimen: 42 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 31, Silent 6, Frame Shift Del 6, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APTX | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV58930531; called by muse, mutect2, varscan2
- ARHGEF37 | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as COSV61370339; called by muse, mutect2
- COQ8A | c.1693A>G p.I565V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV62022098; called by muse, mutect2, varscan2
- DNAH9 | c.10037C>T p.S3346F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs780130216, COSV52377365; called by muse, mutect2, varscan2
- DPAGT1 | c.728+1G>A p.X243_splice | Splice Site (SNP) | VAF 44/91 reads (48%) | catalogued as COSV53828115, COSV53830152; called by muse, mutect2, varscan2
- GCFC2 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58083523; called by muse, mutect2, varscan2
- GLI1 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs368078339; called by muse, mutect2, varscan2
- GYG2 | c.248T>A p.I83N | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV58551799; called by muse, mutect2, varscan2
- KPTN | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1394459041, COSV54551993; called by muse, mutect2, varscan2
- LILRB4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs778903434, COSV54408733; called by muse, mutect2, varscan2
- MAPK15 | c.418-2A>T p.X140_splice | Splice Site (SNP) | VAF 7/12 reads (58%) | catalogued as COSV62030291; called by muse, mutect2, varscan2
- MDGA2 | c.2309C>A p.T770K (on ENST00000399232 / NM_001113498.2; = p.T472K on NM_182830.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV62115625; called by muse, mutect2, varscan2
- MKKS | c.1680G>T p.L560F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61399761; called by muse, mutect2, varscan2
- NCAPH | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53638835; called by muse, varscan2
- PCDHGB7 | c.947C>G p.T316R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV54035948; called by mutect2, varscan2
- PCNX2 | c.5768C>T p.S1923F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV50898038; called by muse, mutect2, varscan2
- PDE11A | c.887C>A p.T296K | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1299721819, COSV53706414, COSV99615053; called by muse, mutect2, varscan2
- PHKA1 | c.2566G>A p.V856I | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as COSV59812018; called by muse, mutect2, varscan2
- PLXDC2 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1180069833, COSV65909176; called by mutect2, varscan2
- PRSS16 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57916982; called by muse, mutect2, varscan2
- PTCH1 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753884837, COSV59494396; called by muse, mutect2, varscan2
- RRN3 | c.1598A>G p.N533S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52216973; called by muse, mutect2, varscan2
- RUBCN | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.051); catalogued as COSV56374363; called by muse, mutect2, varscan2
- SCN2A | c.3013A>C p.I1005L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV51855593; called by muse, mutect2, varscan2
- SLC1A1 | c.1475T>C p.L492P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV52058138; called by muse, mutect2, varscan2
- SLC39A5 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57193720; called by muse, mutect2, varscan2
- SLC43A3 | c.1186A>C p.I396L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV61451355; called by muse, mutect2, varscan2
- SLC5A12 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54825065; called by muse, mutect2, varscan2
- TANGO6 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs764687978, COSV55773080, COSV99936378; called by muse, mutect2, varscan2
- TFCP2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV56936168; called by muse, mutect2, varscan2
- TMEM200B | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58054361; called by muse, mutect2, varscan2
- USP28 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50192447; called by muse, mutect2, varscan2
- ZMYND11 | c.834A>G p.I278M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as COSV59082124; called by muse, mutect2, varscan2
- ZNF439 | c.1102T>C p.S368P | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58311160; called by muse, mutect2
- CRNN | c.1167_1181del p.V390_E394del | In Frame Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- NCAPH | c.811_821del p.R271Afs*5 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- PREB | c.702_715del p.Q234Hfs*63 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- SEC23A | c.1740del p.F580Lfs*5 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel
- SYP | c.407_409delinsG p.N136Rfs*20 | Frame Shift Del (DEL) | VAF 28/34 reads (82%) | called by pindel, varscan2*
- TRIO | c.3696del p.L1233Cfs*29 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- UGT2A3 | c.301_302dup p.L101Ffs*9 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- ZNF226 | c.1236del p.H413Ifs*74 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- ABCA4 | c.804C>T p.I268= | Silent (SNP) | VAF 108/229 reads (47%) | catalogued as COSV64676233, COSV64678191; called by muse, mutect2, varscan2
- HSPA1L | c.42C>T p.G14= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV65149125; called by muse, mutect2, varscan2
- IGDCC3 | c.957G>A p.T319= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs368320458; called by muse, mutect2, varscan2
- PTPN22 | c.105T>C p.S35= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV63086686; called by muse, mutect2, varscan2
- SLC26A5 | c.1326C>T p.A442= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV59705961; called by muse, mutect2, varscan2
- USP34 | c.7452T>G p.V2484= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV68406752; called by muse, mutect2, varscan2
